National Lung Screening Trial (NLST) participant 132827 — screening results and lung cancer
Open-access record from the public subset of National Lung Screening Trial clinical data distributed by the NCI Imaging Data Commons (release v24, collection nlst). NLST enrolled current and former heavy smokers aged 55–74 in 2002–2004 and randomised them to three annual screens (T0, T1, T2) with low-dose CT or chest radiography, with follow-up through 2009. Coded values are written out from the NLST data dictionaries; day counts are days from randomisation.
https://doi.org/10.7937/TCIA.HMQ8-J677

Participant
Age at randomisation: 63 years; Gender: female; Race: White; Cigarette smoking status at randomisation: former smoker (to be eligible, former smokers had quit within the previous 15 years); Enrolled through a Lung Screening Study (LSS) centre (from the participant ID range).

Screening results (official result of each annual screen after comparison with prior images; this participant has no completed screen and no CT screening exam record, and the public subset has no trial-arm field)
- T0: No screening result: Not Expected - Cancer in screening window.
- T1: No screening result: Not Expected - Cancer before screening window.
- T2: No screening result: Not Expected - Cancer before screening window.

Lung cancer (1 primary lung cancer record; the first confirmed lung cancer followed a missed screen; study year of the first confirmed lung cancer: T0; the diagnosis is not linked to a positive screen by the trial's diagnostic-procedure linking algorithm)
1. First primary lung cancer, diagnosed day 81, study year T0. Site: lower lobe of lung (ICD-O-3 C34.3), determined from histology. Primary tumour location: right lower lobe. Histology: adenocarcinoma, NOS (ICD-O-3 8140/3). Grade: cannot be assessed (GX). Tumour size on pathology: 62 mm. AJCC 6th edition staging: stage IV (best stage, from clinical TNM); clinical T2 N2 M1 (stage IV). AJCC 7th edition staging: stage IV; clinical T2b N2 M1b. Summary stage: distant.
